Somatic mutation profile of tumor specimen TCGA-2G-AAEW-01A (aliquot TCGA-2G-AAEW-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAEW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Dead; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 31.0 years (11,325 days).
Specimen TCGA-2G-AAEW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29bdf4e1-e8a2-4fa0-b8c2-983de9590ccc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAEW-10A (Blood Derived Normal), aliquot TCGA-2G-AAEW-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eea67f01-732c-44a6-8c21-f50bd01307af

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 2, In Frame Del 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 49/215 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CD | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 31/141 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.26); PolyPhen possibly damaging (0.88); catalogued as rs587777390, CM143040, COSV63128879; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRF4 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1434143908; called by muse, mutect2, varscan2
- ARHGAP30 | c.2216_2218del p.G739del | In Frame Del (DEL) | VAF 56/262 reads (21%) | catalogued as rs1202186564; called by pindel, varscan2
- POLDIP2 | c.849C>A p.H283Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs781900290; called by muse, mutect2, varscan2
- TTC13 | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1431538587; called by muse, mutect2, varscan2
- ARHGEF17 | c.4091C>T p.A1364V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC14 | c.1186T>A p.L396M (on ENST00000488653; = p.L348M on NM_022757.5) | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FOLR2 | c.244C>G p.H82D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL3RA | c.1117C>G p.Q373E | Missense Mutation (SNP) | VAF 70/443 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- LRCH4 | c.1777-2A>G p.X593_splice | Splice Site (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- NCOA3 | c.1768A>C p.R590= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs775211179; called by muse, mutect2, varscan2
- ADAD2 | c.419-236G>A | Intron (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/47 reads (13%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2*
